Somatic mutation profile of tumor specimen TCGA-AG-3732-01A (aliquot TCGA-AG-3732-01A-11D-1657-10) from TCGA case TCGA-AG-3732, project TCGA-READ (Rectum Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage I; Age at diagnosis: 78.1 years (28,521 days).
Specimen TCGA-AG-3732-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1205e35b-43f7-459c-ab60-6c84126ab4a7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AG-3732-11A (Solid Tissue Normal), aliquot TCGA-AG-3732-11A-01D-1657-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/beb97646-45c7-4d73-b8b9-9d4afbb45dab

The open-access MAF lists 86 somatic variants for this specimen: 69 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 47, Silent 16, Frame Shift Del 12, Nonsense Mutation 5, In Frame Del 2, Splice Site 1, Nonstop Mutation 1, RNA 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ERBB2 | c.2089G>T p.V697L | Missense Mutation (SNP) | VAF 19/44 reads (43%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54066645, COSV54070047; called by muse, mutect2, varscan2
- GNAS | c.602G>T p.R201L | Missense Mutation (SNP) | VAF 52/143 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs121913495, CM158823, COSV55670349, COSV55671845; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AFAP1 | c.1666G>C p.G556R | Missense Mutation (SNP) | VAF 63/108 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61798123; called by muse, mutect2, varscan2
- AK5 | c.953A>T p.K318M (on ENST00000354567 / NM_174858.3; = p.K292M on NM_012093.4) | Missense Mutation (SNP) | VAF 50/128 reads (39%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.972); catalogued as COSV60979798; called by muse, mutect2, varscan2
- AMER3 | c.527C>T p.S176L | Missense Mutation (SNP) | VAF 11/35 reads (31%) | SIFT tolerated (1); PolyPhen benign (0.207); catalogued as rs139544644; called by muse, mutect2, varscan2
- CCDC112 | c.505G>A p.D169N | Missense Mutation (SNP) | VAF 95/178 reads (53%) | SIFT deleterious (0.05); PolyPhen benign (0.232); catalogued as COSV65473819; called by muse, mutect2, varscan2
- CDK14 | c.629T>C p.F210S (on ENST00000380050 / NM_001287135.2; = p.F192S on NM_012395.3) | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV56049047; called by muse, mutect2, varscan2
- CKB | c.143C>G p.P48R | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV62379693; called by muse, mutect2
- CLNS1A | c.558G>T p.E186D | Missense Mutation (SNP) | VAF 60/303 reads (20%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.777); catalogued as COSV54440760; called by muse, mutect2, varscan2
- CNTN5 | c.3007G>A p.E1003K | Missense Mutation (SNP) | VAF 59/195 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs201638465, COSV54278829; called by muse, mutect2, varscan2
- CSGALNACT2 | c.1576G>A p.E526K | Missense Mutation (SNP) | VAF 62/192 reads (32%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.98); catalogued as COSV65678151; called by muse, mutect2, varscan2
- DMAP1 | c.509G>A p.R170H | Missense Mutation (SNP) | VAF 100/277 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs769155056, COSV60001591; called by muse, mutect2, varscan2
- DSCAM | c.5069_5082del p.D1690Gfs*2 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | catalogued as COSV68034118; called by mutect2, pindel, varscan2
- EPRS1 | c.3714_3732del p.T1240Rfs*30 | Frame Shift Del (DEL) | VAF 52/171 reads (30%) | catalogued as COSV65101170; called by mutect2, pindel, varscan2
- ESCO1 | c.1814T>A p.L605* | Nonsense Mutation (SNP) | VAF 32/128 reads (25%) | catalogued as COSV52522283; called by muse, mutect2, varscan2
- F2RL2 | c.1076T>G p.F359C | Missense Mutation (SNP) | VAF 38/118 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.052); catalogued as COSV56971839; called by muse, mutect2, varscan2
- F8 | c.2951C>T p.S984L | Missense Mutation (SNP) | VAF 57/169 reads (34%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs781861130, COSV64270979; called by muse, mutect2, varscan2
- FAM160B1 | c.1700A>G p.K567R | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.006); catalogued as rs1399207032, COSV100985429; called by muse, mutect2
- FGD5 | c.1151C>T p.A384V | Missense Mutation (SNP) | VAF 21/65 reads (32%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0); catalogued as rs374659688; called by muse, mutect2, varscan2
- FGD5 | c.1447C>T p.R483W | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.07); PolyPhen benign (0.273); catalogued as rs560710091, COSV53250204; called by muse, mutect2, varscan2
- GOLGB1 | c.2806A>G p.N936D | Missense Mutation (SNP) | VAF 38/199 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.213); catalogued as rs764086634, COSV100510829; called by muse, mutect2, varscan2
- GPR174 | c.157C>T p.R53* | Nonsense Mutation (SNP) | VAF 15/280 reads (5%) | catalogued as rs1333054510, COSV52133979; called by muse, mutect2
- IGHG4 | c.404G>A p.R135Q | Missense Mutation (SNP) | VAF 36/158 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs374177525; called by muse, mutect2, varscan2
- IL17RC | c.1244C>T p.P415L (on ENST00000295981 / NM_153461.4; = p.P329L on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.998); catalogued as rs151311782; called by muse, mutect2, varscan2
- KCNH8 | c.1112C>T p.A371V | Missense Mutation (SNP) | VAF 87/226 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs751337521, COSV60474184; called by muse, mutect2, varscan2
- KLHDC2 | c.596del p.D199Vfs*11 | Frame Shift Del (DEL) | VAF 47/151 reads (31%) | catalogued as COSV53588297; called by mutect2, pindel, varscan2
- KRT85 | c.92G>A p.R31H | Missense Mutation (SNP) | VAF 16/51 reads (31%) | SIFT tolerated (0.47); PolyPhen benign (0.012); catalogued as rs1471973724, COSV57736445; called by muse, mutect2, varscan2
- KRTAP8-1 | c.161A>G p.Y54C | Missense Mutation (SNP) | VAF 11/47 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.995); catalogued as rs1172335477, COSV61598302; called by muse, mutect2, varscan2
- LRFN1 | c.685G>A p.G229R | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.32); catalogued as rs1188224153, COSV50455075; called by muse, mutect2, varscan2
- LRRC57 | c.284A>G p.N95S | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.698); catalogued as rs762279497, COSV53000988; called by muse, mutect2, varscan2
- NID2 | c.1639G>A p.V547M | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs149213118; called by muse, mutect2, varscan2
- NIPSNAP2 | c.224A>C p.K75T | Missense Mutation (SNP) | VAF 38/608 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100436719; called by muse, mutect2
- OR52E4 | c.499C>T p.R167C | Missense Mutation (SNP) | VAF 28/207 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as rs757270158, COSV57623791, COSV57625916; called by muse, mutect2, varscan2
- P2RX3 | c.742G>A p.D248N | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.59); PolyPhen benign (0.228); catalogued as COSV54442103; called by muse, mutect2, varscan2
- PTPRD | c.4364C>G p.T1455R | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61974664, COSV61975361, COSV61984311; called by muse, mutect2
- RAD50 | c.3677G>T p.G1226V | Missense Mutation (SNP) | VAF 101/179 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99528946; called by muse, mutect2, varscan2
- RASGRF2 | c.1652A>T p.D551V | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.851); catalogued as COSV54137653; called by muse, mutect2, varscan2
- RNF148 | c.420T>A p.F140L | Missense Mutation (SNP) | VAF 76/247 reads (31%) | SIFT tolerated (0.22); PolyPhen benign (0.102); catalogued as COSV57381545; called by muse, mutect2, varscan2
- SBSPON | c.296G>A p.R99H | Missense Mutation (SNP) | VAF 66/137 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs758346150, COSV52076084, COSV52076182; called by muse, mutect2, varscan2
- SFRP4 | c.367C>G p.L123V | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.998); catalogued as COSV52261051, COSV52261589; called by muse, mutect2, varscan2
- SLC1A6 | c.1088T>A p.F363Y | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.213); catalogued as COSV55673475; called by muse, mutect2, varscan2
- SMC1B | c.2272C>T p.R758* | Nonsense Mutation (SNP) | VAF 34/142 reads (24%) | catalogued as rs758779566, COSV62532925; called by muse, mutect2, varscan2
- SORT1 | c.634C>T p.L212F | Missense Mutation (SNP) | VAF 18/128 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs867497656, COSV56669350; called by muse, mutect2, varscan2
- SPEG | c.8989G>A p.V2997M | Missense Mutation (SNP) | VAF 11/37 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs989465855, COSV56678062; called by muse, mutect2, varscan2
- SRCAP | c.3615_3624del p.K1205Nfs*9 | Frame Shift Del (DEL) | VAF 24/59 reads (41%) | catalogued as COSV52679457; called by mutect2, pindel, varscan2
- SRI | c.440G>A p.R147Q | Missense Mutation (SNP) | VAF 64/168 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748393938, COSV56001457; called by muse, mutect2, varscan2
- SYNE1 | c.25241C>T p.T8414M (on ENST00000367255 / NM_182961.4; = p.T8366M on NM_033071.3) | Missense Mutation (SNP) | VAF 21/82 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.855); catalogued as rs759512753, COSV54946518; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TBC1D12 | c.2113C>T p.R705* | Nonsense Mutation (SNP) | VAF 94/296 reads (32%) | catalogued as rs769285606, COSV56557447; called by muse, mutect2, varscan2
- THUMPD1 | c.14C>T p.A5V | Missense Mutation (SNP) | VAF 15/29 reads (52%) | SIFT tolerated, low confidence (0.87); PolyPhen benign (0); catalogued as rs368837394; called by muse, mutect2, varscan2
- TLR8 | c.1001C>T p.T334M (on ENST00000218032 / NM_138636.5; = p.T352M on NM_016610.4) | Missense Mutation (SNP) | VAF 15/82 reads (18%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.841); catalogued as rs1255052346, COSV54320025; called by muse, mutect2, varscan2
- TRIM56 | c.172G>T p.E58* | Nonsense Mutation (SNP) | VAF 18/37 reads (49%) | catalogued as COSV60160992; called by muse, mutect2, varscan2
- UGT3A2 | c.1402G>A p.A468T | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.779); catalogued as rs200458466, COSV56929077; called by muse, varscan2
- WDR13 | c.211G>A p.E71K | Missense Mutation (SNP) | VAF 15/38 reads (39%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as COSV54333308; called by muse, mutect2, varscan2
- ZBTB1 | c.1227C>G p.N409K | Missense Mutation (SNP) | VAF 39/115 reads (34%) | SIFT tolerated (0.94); PolyPhen benign (0.007); catalogued as COSV62439623; called by muse, mutect2, varscan2
- ZEB1 | c.2690G>A p.R897Q | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT deleterious (0.01); PolyPhen benign (0.089); catalogued as rs35653460, COSV58054541; called by muse, mutect2, varscan2
- ZKSCAN2 | c.2716C>T p.R906W | Missense Mutation (SNP) | VAF 52/142 reads (37%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.659); catalogued as COSV60155537; called by muse, mutect2, varscan2
- CDH15 | c.1971del p.G658Efs*21 | Frame Shift Del (DEL) | VAF 18/37 reads (49%) | called by mutect2, pindel, varscan2
- HOXB5 | c.150_167del p.G51_V56del | In Frame Del (DEL) | VAF 10/34 reads (29%) | called by mutect2, pindel
- IP6K3 | c.562_571del p.S188Qfs*14 | Frame Shift Del (DEL) | VAF 11/71 reads (15%) | called by mutect2, pindel, varscan2
- MUC5AC | c.55_59del p.A19Hfs*99 | Frame Shift Del (DEL) | VAF 6/12 reads (50%) | called by mutect2, varscan2
- NOXO1 | c.603_618del p.W202Tfs*29 (on ENST00000397280 / NM_172168.3; = p.W196Tfs*29 on NM_144603.4) | Frame Shift Del (DEL) | VAF 12/29 reads (41%) | called by mutect2, pindel, varscan2
- OTOP3 | c.539_541dup p.F180dup | In Frame Ins (INS) | VAF 33/110 reads (30%) | called by mutect2, pindel, varscan2
- PDSS1 | c.906_912+11delinsCTAGTAGTATGC p.X302_splice | Splice Site (DEL) | VAF 32/133 reads (24%) | called by pindel, varscan2*
- PI4KA | c.5531_5546del p.W1844Sfs*47 | Frame Shift Del (DEL) | VAF 12/58 reads (21%) | called by mutect2, pindel, varscan2
- PLA2G1B | c.421_447del p.D141_*149delext*11 | Nonstop Mutation (DEL) | VAF 66/375 reads (18%) | called by mutect2, pindel, varscan2
- SLC35G6 | c.526_539del p.G176Tfs*69 | Frame Shift Del (DEL) | VAF 29/54 reads (54%) | called by mutect2, pindel, varscan2
- TP53 | c.491_494del p.K164Sfs*5 | Frame Shift Del (DEL) | VAF 15/21 reads (71%) | called by mutect2, varscan2
- TTC16 | c.1169_1187del p.Q390Lfs*84 | Frame Shift Del (DEL) | VAF 19/53 reads (36%) | called by mutect2, pindel, varscan2
- XRN1 | c.593_595del p.T198del | In Frame Del (DEL) | VAF 146/406 reads (36%) | called by mutect2, pindel, varscan2
- ANGPT4 | c.1059C>T p.F353= | Silent (SNP) | VAF 10/25 reads (40%) | catalogued as rs112090528; called by muse, mutect2, varscan2
- ANK2 | c.9396C>T p.F3132= | Silent (SNP) | VAF 34/59 reads (58%) | catalogued as COSV52183447; called by muse, mutect2, varscan2
- ASPH | c.2118C>T p.N706= | Silent (SNP) | VAF 96/176 reads (55%) | catalogued as rs554349058, COSV101063847; called by muse, mutect2, varscan2
- ASPM | c.1680C>T p.N560= | Silent (SNP) | VAF 192/481 reads (40%) | catalogued as rs751204699, COSV54136887; called by muse, mutect2, varscan2
- CACNA1H | c.3987C>T p.S1329= | Silent (SNP) | VAF 18/42 reads (43%) | catalogued as rs770769436, COSV62001478; called by muse, mutect2, varscan2
- CHRDL2 | c.231G>A p.P77= | Silent (SNP) | VAF 9/35 reads (26%) | catalogued as rs555934347, COSV55224815; called by muse, mutect2, varscan2
- ERICH6 | c.711G>A p.T237= | Silent (SNP) | VAF 40/109 reads (37%) | catalogued as rs750322011, COSV55802709; called by muse, mutect2, varscan2
- FAT1 | c.504C>T p.I168= | Silent (SNP) | VAF 72/121 reads (60%) | catalogued as rs775357680, COSV71675621; called by muse, mutect2, varscan2
- GPR152 | c.1104G>A p.S368= | Silent (SNP) | VAF 51/126 reads (40%) | catalogued as rs754240741, COSV56887868; called by muse, mutect2, varscan2
- IQGAP1 | c.3750C>A p.I1250= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as COSV51590208; called by muse, mutect2, varscan2
- IRX1 | c.1026C>T p.G342= | Silent (SNP) | VAF 7/21 reads (33%) | catalogued as COSV57361951; called by muse, mutect2, varscan2
- LCAT | c.12C>T p.P4= | Silent (SNP) | VAF 18/37 reads (49%) | catalogued as rs912256784, COSV50454645; called by muse, mutect2, varscan2
- LRRK1 | c.2358C>T p.S786= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as rs370178353; called by muse, mutect2, varscan2
- NYAP2 | c.1371C>T p.Y457= | Silent (SNP) | VAF 18/107 reads (17%) | catalogued as rs750472721, COSV55998444; called by muse, mutect2, varscan2
- SREBF2 | c.2601C>T p.A867= | Silent (SNP) | VAF 15/59 reads (25%) | catalogued as COSV100761442, COSV63332256; called by muse, mutect2, varscan2
- TAF4 | c.1500C>T p.P500= | Silent (SNP) | VAF 27/61 reads (44%) | catalogued as rs764367337, COSV53334342; called by muse, mutect2, varscan2
- FAM27E5 | n.415C>T | RNA (SNP) | VAF 24/71 reads (34%) | catalogued as rs768338600; called by muse, mutect2, varscan2
